Gene-level copy-number profile of tumor specimen TCGA-WE-AA9Y-06A from TCGA case TCGA-WE-AA9Y, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Superficial spreading melanoma; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 38.0 years (13,884 days).
Specimen TCGA-WE-AA9Y-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.3eb6cded-390b-4f4c-afb8-edf50df3a5a2.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-WE-AA9Y-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/178ae585-f0f9-4564-a0f5-892e07370de9

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,398; copy number 2: 56,622; copy number 3: 719; copy number 4: 42; copy number 6: 28; copy number 7: 3; copy number 8: 7.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-WE-AA9Y-06A-12D-A38F-01): tumor purity 0.28, ploidy 1.88, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 38 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:119,648,411–119,896,515, 7 genes, copy number 8 (within-gene range 2–8): PHGDH, HMGCS2, REG4, NBPF7, PFN1P9, NOTCH2P1, ADAM30.
- chr17:31,090,787–31,382,116, 8 genes, copy number 6 (within-gene range 2–6): AC138207.2, MIR4733, NF1, AC079915.1, OMG, EVI2B, AC134669.1, EVI2A.
- chr17:33,680,577–33,692,484, 3 genes, copy number 7: AC024614.1, AC024614.2, AC024614.3.
- chr17:33,935,437–34,156,000, 1 gene, copy number 6 (within-gene range 2–6): AC004147.4.
- chr17:34,036,681–34,639,318, 19 genes, copy number 6: TLK2P1, AC004147.1, AC004147.5, RNA5SP438, AC004147.3, AC004147.2, LINC01989, AC005549.1, CCL2, CCL7, CCL11, CCL8, AC011193.2, CCL13, CCL1, AC011193.1, C17orf102, TMEM132E, AC005691.1.

Autosomal genes at a single copy (total copy number 1): 11. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
